Somatic mutation profile of tumor specimen ALCH-B37J-TTP1-A (aliquot ALCH-B37J-TTP1-A-1-0-D-A780-36) from ALCHEMIST case ALCH-B37J, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 76.4 years (27,902 days).
Specimen ALCH-B37J-TTP1-A: Sample type: FFPE Scrolls; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 96b1acc4-f4c7-42a0-96b3-6fabfba6efd1.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B37J-NB1-A (Blood Derived Normal), aliquot ALCH-B37J-NB1-A-1-0-D-A780-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/27aecd72-7494-4c41-a2d0-b65ad7bd9e05

The open-access MAF lists 436 somatic variants for this specimen: 304 protein-altering or splice-affecting, 85 silent, 47 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 269, Silent 85, Nonsense Mutation 21, Intron 20, Splice Site 12, RNA 9, 5'UTR 7, 3'UTR 5, 5'Flank 4, 3'Flank 2, Splice Region 1, Translation Start Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- EGFR | c.2155G>T p.G719C | Missense Mutation (SNP) | VAF 52/536 reads (10%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs28929495, COSV51766606, COSV51767289; ClinVar: pathogenic / drug response / likely pathogenic; called by muse, mutect2
- ERBB2 | c.829G>T p.D277Y | Missense Mutation (SNP) | VAF 57/493 reads (12%) | hotspot (GDC flag); SIFT tolerated (0.06); PolyPhen possibly damaging (0.872); catalogued as COSV54062992, COSV54071143; called by muse, mutect2, varscan2
- OTC | c.571C>T p.L191F | Missense Mutation (SNP) | VAF 84/1380 reads (6%) | SIFT tolerated (0.23); PolyPhen benign (0.053); catalogued as rs72556296, CD065770, CM020172; ClinVar: pathogenic; called by muse, mutect2
- ACAN | c.1693G>A p.E565K | Missense Mutation (SNP) | VAF 12/310 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.708); catalogued as rs1382905147; called by muse, mutect2
- ADGRB3 | c.3934C>A p.P1312T | Missense Mutation (SNP) | VAF 23/377 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99482987, COSV99483918; called by muse, mutect2
- ADGRB3 | c.3935C>T p.P1312L | Missense Mutation (SNP) | VAF 23/372 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV53261881; called by muse, mutect2
- AL136295.1 | c.1715T>G p.F572C | Missense Mutation (SNP) | VAF 32/710 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV55781189; called by muse, mutect2
- ALMS1 | c.4516C>T p.P1506S | Missense Mutation (SNP) | VAF 16/292 reads (5%) | SIFT tolerated (0.37); PolyPhen benign (0.12); catalogued as rs1233912426; called by muse, mutect2
- ANKRD30B | c.1961C>A p.T654N | Missense Mutation (SNP) | VAF 18/374 reads (5%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.958); catalogued as COSV62825165; called by muse, mutect2
- ASPM | c.7879G>T p.A2627S | Missense Mutation (SNP) | VAF 68/1441 reads (5%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.812); catalogued as COSV54129801; called by muse, mutect2
- BORCS6 | c.493G>A p.D165N | Missense Mutation (SNP) | VAF 6/106 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); catalogued as rs1169346272; called by muse, mutect2
- BRINP2 | c.427G>C p.G143R | Missense Mutation (SNP) | VAF 21/419 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64177852; called by muse, mutect2
- CXCR4 | c.32A>T p.N11I | Missense Mutation (SNP) | VAF 44/722 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.055); catalogued as COSV54016990; called by muse, mutect2
- DMD | c.844C>A p.L282I | Missense Mutation (SNP) | VAF 30/538 reads (6%) | SIFT tolerated (0.23); PolyPhen benign (0.132); catalogued as rs1188593868; called by muse, mutect2
- DNAH8 | c.4603G>T p.A1535S | Missense Mutation (SNP) | VAF 24/582 reads (4%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV59481968; called by muse, mutect2
- DNAL4 | c.151G>T p.E51* | Nonsense Mutation (SNP) | VAF 16/378 reads (4%) | catalogued as COSV53308750, COSV53309017, COSV99326134; called by muse, mutect2
- DSC1 | c.148+1G>T p.X50_splice | Splice Site (SNP) | VAF 40/906 reads (4%) | catalogued as rs1393334760; called by muse, mutect2
- EBP | c.616G>T p.D206Y | Missense Mutation (SNP) | VAF 20/584 reads (3%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.954); catalogued as CM086600, COSV99339332; called by muse, mutect2
- EIF4G1 | c.4480G>T p.E1494* (on ENST00000346169 / NM_198241.3; = p.E1299* on NM_004953.5) | Nonsense Mutation (SNP) | VAF 48/894 reads (5%) | catalogued as COSV100071819; called by muse, mutect2
- ENAM | c.1766A>G p.H589R | Missense Mutation (SNP) | VAF 13/174 reads (7%) | SIFT tolerated (0.11); PolyPhen benign (0.029); catalogued as COSV68537065; called by muse, mutect2
- FAM83E | c.1173C>A p.N391K | Missense Mutation (SNP) | VAF 14/135 reads (10%) | SIFT tolerated (0.13); PolyPhen benign (0.022); catalogued as rs1377208490; called by muse, mutect2, varscan2
- FAT3 | c.12541C>G p.R4181G | Missense Mutation (SNP) | VAF 25/620 reads (4%) | SIFT deleterious (0.02); PolyPhen benign (0.444); catalogued as rs1012397377, COSV53119575; called by muse, mutect2
- FLG2 | c.4222C>G p.Q1408E | Missense Mutation (SNP) | VAF 30/563 reads (5%) | SIFT tolerated (0.08); PolyPhen benign (0.019); catalogued as rs1425700657; called by muse, mutect2
- FLG2 | c.2128G>T p.G710W | Missense Mutation (SNP) | VAF 75/1348 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.979); catalogued as COSV101165780; called by muse, mutect2
- FLRT2 | c.10C>T p.Q4* | Nonsense Mutation (SNP) | VAF 6/111 reads (5%) | catalogued as COSV100420710; called by muse, mutect2
- FNDC1 | c.206C>A p.P69H | Missense Mutation (SNP) | VAF 26/501 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV99795939; called by muse, mutect2
- FOLH1 | c.1580G>T p.R527L | Missense Mutation (SNP) | VAF 29/797 reads (4%) | SIFT deleterious (0.01); PolyPhen benign (0.322); catalogued as COSV57048182; called by muse, mutect2
- FOXP4 | c.1264C>G p.L422V (on ENST00000307972 / NM_001012426.1; = p.L409V on NM_138457.3) | Missense Mutation (SNP) | VAF 10/60 reads (17%) | SIFT tolerated (0.31); PolyPhen benign (0.074); catalogued as rs779277938, COSV57222647; called by mutect2, varscan2
- GALNT14 | c.575G>A p.G192D | Missense Mutation (SNP) | VAF 19/221 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); catalogued as rs149891806; called by muse, mutect2
- GBP4 | c.601G>T p.E201* | Nonsense Mutation (SNP) | VAF 22/517 reads (4%) | catalogued as COSV63254435; called by muse, mutect2
- GZMB | c.685G>T p.A229S | Missense Mutation (SNP) | VAF 34/641 reads (5%) | SIFT deleterious (0); PolyPhen benign (0.161); catalogued as rs748428522; called by muse, mutect2
- HGF | c.1616G>T p.R539L | Missense Mutation (SNP) | VAF 28/698 reads (4%) | SIFT tolerated (0.07); PolyPhen benign (0.315); catalogued as COSV55948847, COSV99735809; called by muse, mutect2
- HTR1A | c.305G>T p.W102L | Missense Mutation (SNP) | VAF 24/444 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60499659; called by muse, mutect2
- IGLV3-1 | c.286A>T p.T96S | Missense Mutation (SNP) | VAF 84/874 reads (10%) | SIFT deleterious (0.02); PolyPhen benign (0.027); catalogued as rs774168565; called by muse, mutect2
- IGSF1 | c.3292C>A p.L1098M | Missense Mutation (SNP) | VAF 62/1080 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV63835863; called by muse, mutect2
- INPP4B | c.2726C>A p.P909H | Missense Mutation (SNP) | VAF 28/658 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53743292; called by muse, mutect2
- KIAA2013 | c.1856G>T p.G619V | Missense Mutation (SNP) | VAF 28/356 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV64860913; called by muse, mutect2
- KPRP | c.1438C>A p.P480T | Missense Mutation (SNP) | VAF 8/152 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.906); catalogued as COSV64221693; called by muse, mutect2
- KPRP | c.1439C>G p.P480R | Missense Mutation (SNP) | VAF 8/150 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.964); catalogued as COSV64221309; called by muse, mutect2
- KRTAP13-3 | c.356C>A p.S119* | Nonsense Mutation (SNP) | VAF 27/452 reads (6%) | catalogued as COSV61879624; called by muse, mutect2
- KRTAP5-11 | c.242G>C p.G81A | Missense Mutation (SNP) | VAF 14/305 reads (5%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.001); catalogued as COSV100651811; called by muse, mutect2
- KTN1 | c.1937T>C p.L646S | Missense Mutation (SNP) | VAF 26/370 reads (7%) | SIFT tolerated (0.62); PolyPhen benign (0.026); catalogued as COSV101255101; called by muse, mutect2
- LAMB4 | c.4203G>T p.R1401S | Missense Mutation (SNP) | VAF 52/578 reads (9%) | SIFT tolerated (0.07); PolyPhen benign (0.003); catalogued as COSV99225208; called by muse, mutect2
- LILRB1 | c.634G>T p.G212W (on ENST00000427581; = p.G176W on NM_006669.6) | Missense Mutation (SNP) | VAF 19/522 reads (4%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.482); catalogued as COSV100207847; called by muse, mutect2
- LRRC4C | c.118G>T p.G40C | Missense Mutation (SNP) | VAF 21/424 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV53417523, COSV99539805; called by muse, mutect2
- LRRC7 | c.3481A>G p.T1161A (on ENST00000651989 / NM_001370785.2; = p.T1128A on NM_001330635.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 21/262 reads (8%) | SIFT tolerated (0.23); PolyPhen benign (0.054); catalogued as rs1420203568; called by muse, mutect2
- MAB21L1 | c.140T>G p.V47G | Missense Mutation (SNP) | VAF 50/894 reads (6%) | SIFT tolerated (0.37); PolyPhen benign (0.164); catalogued as COSV59760218; called by muse, mutect2
- MCM10 | c.3G>T p.M1? | Translation Start Site (SNP) | VAF 10/266 reads (4%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.035); catalogued as COSV66333088; called by muse, mutect2
- MEGF10 | c.1438G>T p.V480L | Missense Mutation (SNP) | VAF 8/98 reads (8%) | SIFT tolerated (0.77); PolyPhen benign (0.007); catalogued as rs1248824615; called by muse, mutect2
- MUC16 | c.29560G>C p.V9854L | Missense Mutation (SNP) | VAF 35/486 reads (7%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.001); catalogued as rs777355694, COSV67450415; called by muse, mutect2
- MUC16 | c.15076G>A p.V5026I | Missense Mutation (SNP) | VAF 8/188 reads (4%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.231); catalogued as rs1348845745; called by muse, mutect2
- MUC16 | c.8396G>A p.G2799E | Missense Mutation (SNP) | VAF 16/306 reads (5%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.116); catalogued as COSV67451534, COSV67463967; called by muse, mutect2
- MUC16 | c.1793C>T p.P598L | Missense Mutation (SNP) | VAF 41/475 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.197); catalogued as COSV101200082; called by muse, mutect2
- MUSK | c.1390C>A p.P464T | Missense Mutation (SNP) | VAF 10/139 reads (7%) | SIFT deleterious (0.03); PolyPhen benign (0.003); catalogued as COSV51892830; called by muse, mutect2
- NAALAD2 | c.1084G>T p.V362F | Missense Mutation (SNP) | VAF 25/405 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV100428902; called by muse, mutect2
- NLRP5 | c.1164C>A p.F388L | Missense Mutation (SNP) | VAF 16/387 reads (4%) | SIFT tolerated (0.62); PolyPhen benign (0.019); catalogued as COSV66762126; called by muse, mutect2
- NR4A2 | c.1001G>T p.R334L | Missense Mutation (SNP) | VAF 14/350 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV59895074; called by muse, mutect2
- OR10H5 | c.547C>T p.P183S | Missense Mutation (SNP) | VAF 18/382 reads (5%) | SIFT tolerated (0.17); PolyPhen benign (0.07); catalogued as COSV58277824; called by muse, mutect2
- OR5L2 | c.477C>A p.H159Q | Missense Mutation (SNP) | VAF 26/532 reads (5%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as COSV65724966; called by muse, mutect2
- OTOP1 | c.1077G>A p.M359I | Missense Mutation (SNP) | VAF 41/516 reads (8%) | SIFT tolerated (0.5); PolyPhen benign (0.031); catalogued as rs780470763; called by muse, mutect2
- PASD1 | c.839C>G p.P280R | Missense Mutation (SNP) | VAF 16/252 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.815); catalogued as COSV64854941; called by muse, mutect2
- PCDH19 | c.3410C>A p.S1137Y (on ENST00000373034 / NM_001184880.2; = p.S1089Y on NM_020766.3) | Missense Mutation (SNP) | VAF 28/668 reads (4%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.986); catalogued as COSV55273333; called by muse, mutect2
- PCDHB3 | c.973G>C p.G325R | Missense Mutation (SNP) | VAF 32/600 reads (5%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.993); catalogued as COSV50564161; called by muse, mutect2
- PCDHGA6 | c.2288C>A p.S763* | Nonsense Mutation (SNP) | VAF 40/718 reads (6%) | catalogued as COSV53993090; called by muse, mutect2
- PLK2 | c.1733A>G p.Y578C | Missense Mutation (SNP) | VAF 40/381 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.99); catalogued as COSV57105609; called by muse, mutect2
- PLXNA4 | c.271G>T p.D91Y | Missense Mutation (SNP) | VAF 27/300 reads (9%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV58115503; called by muse, mutect2
- POTEE | c.320C>T p.P107L | Missense Mutation (SNP) | VAF 26/460 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.713); catalogued as COSV100387339; called by muse, mutect2
- PPP1R32 | c.518G>A p.R173H | Missense Mutation (SNP) | VAF 24/320 reads (8%) | SIFT tolerated (0.15); PolyPhen benign (0.232); catalogued as rs749267989, COSV58546344; called by muse, mutect2
- PPP1R3B | c.391G>T p.D131Y | Missense Mutation (SNP) | VAF 38/580 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.935); catalogued as COSV60099431; called by muse, mutect2
- RBM10 | c.790G>T p.E264* | Nonsense Mutation (SNP) | VAF 13/161 reads (8%) | catalogued as COSV100237272; called by muse, mutect2
- RGPD4 | c.3764G>T p.R1255M | Missense Mutation (SNP) | VAF 82/1814 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV61746080; called by muse, mutect2
- RGPD4 | c.3765G>T p.R1255S | Missense Mutation (SNP) | VAF 80/1816 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); catalogued as COSV61748757; called by muse, mutect2
- RGPD4 | c.5134C>T p.H1712Y | Missense Mutation (SNP) | VAF 86/1646 reads (5%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs2581008; called by muse, mutect2
- RNF133 | c.401G>T p.G134V | Missense Mutation (SNP) | VAF 42/344 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100411404, COSV57387212; called by muse, mutect2, varscan2
- RNF150 | c.155C>A p.A52E | Missense Mutation (SNP) | VAF 7/138 reads (5%) | SIFT tolerated (0.87); PolyPhen benign (0.003); catalogued as COSV60800154; called by muse, mutect2
- RNF212 | c.449C>T p.S150L | Missense Mutation (SNP) | VAF 40/698 reads (6%) | SIFT tolerated (0.12); PolyPhen benign (0.018); catalogued as rs371785141; called by muse, mutect2
- RTL1 | c.2869C>A p.L957M | Missense Mutation (SNP) | VAF 23/302 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); catalogued as COSV101128295; called by muse, mutect2
- SAMD9 | c.264G>T p.M88I | Missense Mutation (SNP) | VAF 37/868 reads (4%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as COSV101180273; called by muse, mutect2
- SGIP1 | c.1508C>G p.A503G | Missense Mutation (SNP) | VAF 32/784 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); catalogued as COSV52770104, COSV52770638, COSV99392643; called by muse, mutect2
- SLC12A3 | c.2099T>A p.L700Q | Missense Mutation (SNP) | VAF 26/426 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as CM160524; called by muse, mutect2
- SLC25A14 | c.785G>T p.R262L | Missense Mutation (SNP) | VAF 50/714 reads (7%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.478); catalogued as COSV99502276; called by muse, mutect2
- STMND1 | c.578G>A p.S193N | Missense Mutation (SNP) | VAF 14/172 reads (8%) | SIFT tolerated (0.22); PolyPhen benign (0.229); catalogued as rs754629011; called by muse, mutect2
- SYN3 | c.976G>A p.V326M | Missense Mutation (SNP) | VAF 27/618 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.795); catalogued as COSV100249849; called by muse, mutect2
- TAS2R60 | c.135G>T p.E45D | Missense Mutation (SNP) | VAF 46/598 reads (8%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.937); catalogued as COSV60332329; called by muse, mutect2
- TMEM178A | c.556G>C p.A186P | Missense Mutation (SNP) | VAF 16/348 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99931783; called by muse, mutect2
- TRPM1 | c.1606G>T p.V536L | Missense Mutation (SNP) | VAF 52/926 reads (6%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.972); catalogued as rs779702766, COSV56637972; called by muse, mutect2
- TTC14 | c.1214A>G p.Y405C | Missense Mutation (SNP) | VAF 30/356 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs776750324; called by muse, mutect2
- TUBAL3 | c.1139G>T p.R380L | Missense Mutation (SNP) | VAF 6/98 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.236); catalogued as rs368080202, COSV66814675; called by muse, mutect2
- UGT1A1 | c.1208G>T p.R403L | Missense Mutation (SNP) | VAF 50/826 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs140613392; called by muse, mutect2
- USP34 | c.4880A>G p.H1627R | Missense Mutation (SNP) | VAF 31/434 reads (7%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.888); catalogued as COSV68404848; called by muse, mutect2
- ZNF347 | c.442G>T p.A148S | Missense Mutation (SNP) | VAF 33/548 reads (6%) | SIFT tolerated (0.08); PolyPhen benign (0.003); catalogued as COSV61970888; called by muse, mutect2
- ZNF418 | c.313C>A p.H105N | Missense Mutation (SNP) | VAF 18/272 reads (7%) | SIFT tolerated (0.33); PolyPhen possibly damaging (0.838); catalogued as COSV101268911; called by muse, mutect2
- ZNF543 | c.1747G>T p.E583* | Nonsense Mutation (SNP) | VAF 10/158 reads (6%) | catalogued as rs1401526278, COSV100386910; called by muse, mutect2
- ZNF566 | c.1088G>A p.G363E | Missense Mutation (SNP) | VAF 17/294 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV101091277; called by muse, mutect2
- ZNF608 | c.3358G>T p.A1120S | Missense Mutation (SNP) | VAF 11/133 reads (8%) | SIFT tolerated (0.27); PolyPhen benign (0.033); catalogued as COSV60440433; called by muse, mutect2
- ZNF648 | c.1417G>A p.E473K | Missense Mutation (SNP) | VAF 14/176 reads (8%) | SIFT tolerated (0.07); PolyPhen benign (0.362); catalogued as rs546993253, COSV60572506; called by muse, mutect2
- ZNF727 | c.1071C>A p.S357R | Missense Mutation (SNP) | VAF 26/823 reads (3%) | SIFT tolerated (0.61); PolyPhen benign (0); catalogued as rs1173946677, COSV70701869; called by muse, mutect2
- AC006059.2 | c.1277T>A p.L426Q | Missense Mutation (SNP) | VAF 18/301 reads (6%) | SIFT tolerated (0.62); PolyPhen benign (0.198); called by muse, mutect2
- ACE | c.2464G>T p.G822W | Missense Mutation (SNP) | VAF 68/597 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ADAMTS16 | c.2552T>A p.V851D | Missense Mutation (SNP) | VAF 27/365 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.899); called by muse, mutect2
- ADAMTS20 | c.199A>T p.S67C | Missense Mutation (SNP) | VAF 12/380 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2
- AHNAK2 | c.14899C>A p.P4967T | Missense Mutation (SNP) | VAF 16/253 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.934); called by muse, mutect2
- AK7 | c.1281G>T p.E427D | Missense Mutation (SNP) | VAF 30/392 reads (8%) | SIFT tolerated (0.28); PolyPhen benign (0.031); called by muse, mutect2
- ALOX5 | c.1888C>T p.P630S | Missense Mutation (SNP) | VAF 11/346 reads (3%) | SIFT tolerated (0.14); PolyPhen benign (0.205); called by muse, mutect2
- AMER1 | c.3386T>C p.M1129T | Missense Mutation (SNP) | VAF 16/466 reads (3%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0); called by muse, mutect2
- AMMECR1 | c.152C>A p.T51K | Missense Mutation (SNP) | VAF 6/50 reads (12%) | SIFT tolerated, low confidence (0.49); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- ANGPTL1 | c.1460T>A p.I487N | Missense Mutation (SNP) | VAF 14/211 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); called by muse, mutect2
- ANK2 | c.289G>T p.G97* | Nonsense Mutation (SNP) | VAF 46/741 reads (6%) | called by muse, mutect2
- ANK2 | c.3749G>T p.G1250V | Missense Mutation (SNP) | VAF 65/1111 reads (6%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.674); called by muse, mutect2
- ANKRD44 | c.480G>T p.L160F | Missense Mutation (SNP) | VAF 35/772 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- APOA5 | c.161C>A p.A54E | Missense Mutation (SNP) | VAF 40/548 reads (7%) | SIFT tolerated (0.71); PolyPhen benign (0.019); called by muse, mutect2
- AQR | c.2665G>T p.E889* | Nonsense Mutation (SNP) | VAF 23/450 reads (5%) | called by muse, mutect2
- ARAP2 | c.1558-2A>T p.X520_splice | Splice Site (SNP) | VAF 11/171 reads (6%) | called by muse, mutect2
- ARMC3 | c.801G>T p.M267I | Missense Mutation (SNP) | VAF 42/488 reads (9%) | SIFT tolerated (0.13); PolyPhen benign (0.001); called by muse, mutect2
- ARMC3 | c.1674G>T p.Q558H | Missense Mutation (SNP) | VAF 19/427 reads (4%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.514); called by muse, mutect2
- ARMH3 | c.73G>T p.V25L | Missense Mutation (SNP) | VAF 38/1076 reads (4%) | SIFT tolerated (0.16); PolyPhen benign (0.048); called by muse, mutect2
- ASZ1 | c.1015C>T p.Q339* | Nonsense Mutation (SNP) | VAF 28/621 reads (5%) | called by muse, mutect2
- ATXN2L | c.1959A>T p.Q653H | Missense Mutation (SNP) | VAF 22/356 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); called by muse, mutect2
- AXL | c.1724C>A p.T575K (on ENST00000301178 / NM_021913.5; = p.T566K on NM_001699.6) | Missense Mutation (SNP) | VAF 28/388 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- BCOR | c.111C>G p.D37E | Missense Mutation (SNP) | VAF 53/1302 reads (4%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0.028); called by muse, mutect2
- BIRC6 | c.7432G>T p.E2478* | Nonsense Mutation (SNP) | VAF 6/137 reads (4%) | called by muse, mutect2
- BOD1L1 | c.5362G>C p.E1788Q | Missense Mutation (SNP) | VAF 28/552 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2
- BPIFB6 | c.1075-2A>T p.X359_splice | Splice Site (SNP) | VAF 21/439 reads (5%) | called by muse, mutect2
- BPTF | c.985G>A p.V329M | Missense Mutation (SNP) | VAF 20/379 reads (5%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.765); called by muse, mutect2
- BRINP3 | c.898G>T p.E300* | Nonsense Mutation (SNP) | VAF 20/306 reads (7%) | called by muse, mutect2
- BTBD1 | c.847G>T p.E283* | Nonsense Mutation (SNP) | VAF 32/451 reads (7%) | called by muse, mutect2
- C2orf16 | c.3171G>T p.Q1057H | Missense Mutation (SNP) | VAF 34/688 reads (5%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.478); called by muse, mutect2
- CA3 | c.491A>G p.D164G | Missense Mutation (SNP) | VAF 26/339 reads (8%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.997); called by muse, mutect2
- CASTOR1 | c.506-1G>A p.X169_splice | Splice Site (SNP) | VAF 6/52 reads (12%) | called by muse, varscan2
- CASTOR2 | c.373A>G p.I125V | Missense Mutation (SNP) | VAF 38/502 reads (8%) | SIFT tolerated (0.2); PolyPhen benign (0.3); called by muse, mutect2
- CBX3 | c.8C>T p.S3F | Missense Mutation (SNP) | VAF 36/620 reads (6%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0); called by muse, mutect2
- CCDC22 | c.1340C>A p.S447Y | Missense Mutation (SNP) | VAF 16/352 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- CCT8L2 | c.1329G>T p.W443C | Missense Mutation (SNP) | VAF 24/518 reads (5%) | SIFT deleterious (0); PolyPhen benign (0.019); called by muse, mutect2
- CENPF | c.5528G>T p.S1843I | Missense Mutation (SNP) | VAF 15/248 reads (6%) | SIFT tolerated (0.07); PolyPhen benign (0.029); called by muse, mutect2
- CEP170 | c.4414G>T p.E1472* | Nonsense Mutation (SNP) | VAF 16/328 reads (5%) | called by muse, mutect2
- CEP170 | c.4414-1G>T p.X1472_splice | Splice Site (SNP) | VAF 16/321 reads (5%) | called by muse, mutect2
- CEP44 | c.962-1G>T p.X321_splice | Splice Site (SNP) | VAF 40/745 reads (5%) | called by muse, mutect2
- CFAP221 | c.526A>T p.S176C | Missense Mutation (SNP) | VAF 30/322 reads (9%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.98); called by muse, mutect2
- CFAP47 | c.625G>T p.D209Y | Missense Mutation (SNP) | VAF 23/346 reads (7%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.644); called by muse, mutect2
- CFAP54 | c.128G>T p.R43L | Missense Mutation (SNP) | VAF 12/251 reads (5%) | SIFT tolerated, low confidence (0.57); PolyPhen benign (0); called by muse, mutect2
- CFHR1 | c.391G>C p.E131Q | Missense Mutation (SNP) | VAF 91/732 reads (12%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.765); called by muse, mutect2, varscan2
- CHD1L | c.2283G>T p.E761D | Missense Mutation (SNP) | VAF 37/779 reads (5%) | SIFT deleterious (0); PolyPhen benign (0.197); called by muse, mutect2
- CLTCL1 | c.4475A>G p.N1492S | Missense Mutation (SNP) | VAF 26/450 reads (6%) | SIFT tolerated (0.44); PolyPhen benign (0.038); called by muse, mutect2
- COL6A5 | c.6031T>A p.L2011M (on ENST00000312481; = p.L2007M on NM_153264.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 50/886 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2
- COL6A6 | c.4281A>T p.R1427S | Missense Mutation (SNP) | VAF 31/496 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- CPA5 | c.470C>A p.S157Y | Missense Mutation (SNP) | VAF 32/550 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.863); called by muse, mutect2
- CSMD3 | c.11093C>A p.P3698H (on ENST00000297405 / NM_001363185.1; = p.P3529H on NM_052900.3) | Missense Mutation (SNP) | VAF 42/642 reads (7%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); called by muse, mutect2
- CYLC1 | c.522G>T p.K174N | Missense Mutation (SNP) | VAF 12/170 reads (7%) | SIFT tolerated (0.07); PolyPhen benign (0.029); called by muse, mutect2
- CYP1A1 | c.958G>C p.D320H | Missense Mutation (SNP) | VAF 14/310 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2
- CYP4F11 | c.1314+1G>A p.X438_splice | Splice Site (SNP) | VAF 12/260 reads (5%) | called by muse, mutect2
- CYP4F11 | c.1314G>T p.E438D | Missense Mutation (SNP) | VAF 12/264 reads (5%) | SIFT deleterious (0.03); PolyPhen benign (0.25); called by muse, mutect2
- CYP4F22 | c.869G>T p.G290V | Missense Mutation (SNP) | VAF 10/120 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.976); called by muse, mutect2
- DACT1 | c.1281A>T p.Q427H | Missense Mutation (SNP) | VAF 30/504 reads (6%) | SIFT tolerated (0.09); PolyPhen benign (0.006); called by muse, mutect2
- DCHS2 | c.1820C>A p.A607D | Missense Mutation (SNP) | VAF 8/164 reads (5%) | SIFT tolerated (0.2); PolyPhen benign (0.245); called by muse, mutect2
- DENND2A | c.766G>T p.G256C | Missense Mutation (SNP) | VAF 7/47 reads (15%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.566); called by muse, mutect2, varscan2
- DENND5B | c.2018G>T p.W673L | Missense Mutation (SNP) | VAF 16/307 reads (5%) | SIFT tolerated (0.09); PolyPhen benign (0.003); called by muse, mutect2
- DIPK2B | c.628C>A p.L210M | Missense Mutation (SNP) | VAF 8/74 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- DLX4 | c.410A>G p.Q137R (on ENST00000240306 / NM_138281.3; = p.Q65R on NM_001934.3) | Missense Mutation (SNP) | VAF 14/199 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.345); called by muse, mutect2
- DNAH2 | c.11137G>A p.G3713S | Missense Mutation (SNP) | VAF 12/192 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.893); called by muse, mutect2
- DOCK10 | c.5054A>T p.Q1685L | Missense Mutation (SNP) | VAF 65/1097 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.448); called by muse, mutect2
- DPEP1 | c.988A>T p.R330W | Missense Mutation (SNP) | VAF 21/277 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.951); called by muse, mutect2
- DYNC2H1 | c.2446G>T p.V816L | Missense Mutation (SNP) | VAF 17/553 reads (3%) | SIFT tolerated (0.16); PolyPhen benign (0.012); called by muse, mutect2
- EIF3L | c.116A>T p.Q39L | Missense Mutation (SNP) | VAF 20/382 reads (5%) | SIFT deleterious (0.01); PolyPhen benign (0.083); called by muse, mutect2
- ELMOD1 | c.488G>T p.G163V | Missense Mutation (SNP) | VAF 23/828 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- ELP4 | c.784G>T p.G262C (on ENST00000350638; = p.G261C on NM_019040.5) | Missense Mutation (SNP) | VAF 28/496 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2
- EP400 | c.2359G>A p.A787T | Missense Mutation (SNP) | VAF 10/146 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); called by muse, mutect2
- EPHA6 | c.2519C>A p.P840Q (on ENST00000389672 / NM_001080448.3; = p.P232Q on NM_173655.4) | Missense Mutation (SNP) | VAF 28/827 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- EPS15 | c.1583G>T p.S528I | Missense Mutation (SNP) | VAF 61/1134 reads (5%) | SIFT tolerated (0.12); PolyPhen benign (0.339); called by muse, mutect2
- EPS8L3 | c.1637+1G>T p.X546_splice (on ENST00000361965 / NM_133181.4; = p.X516_splice on NM_024526.4 and 1 other RefSeq transcript) | Splice Site (SNP) | VAF 26/417 reads (6%) | called by muse, mutect2
- FAM47A | c.1975G>T p.E659* | Nonsense Mutation (SNP) | VAF 7/166 reads (4%) | called by muse, mutect2
- FBL | c.712G>T p.A238S | Missense Mutation (SNP) | VAF 18/459 reads (4%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.828); called by muse, mutect2
- FKBP9 | c.1099C>T p.P367S | Missense Mutation (SNP) | VAF 58/602 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); called by muse, mutect2
- FLNB | c.7228A>T p.T2410S | Missense Mutation (SNP) | VAF 64/984 reads (7%) | SIFT tolerated (0.72); PolyPhen benign (0.07); called by muse, mutect2
- FPR3 | c.198C>G p.N66K | Missense Mutation (SNP) | VAF 14/225 reads (6%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.919); called by muse, mutect2
- FRMPD4 | c.2431C>A p.P811T | Missense Mutation (SNP) | VAF 10/134 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- GDPD2 | c.703-1G>A p.X235_splice | Splice Site (SNP) | VAF 30/414 reads (7%) | called by muse, mutect2
- GRK3 | c.2021A>T p.E674V | Missense Mutation (SNP) | VAF 17/392 reads (4%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.25); called by muse, mutect2
- HAPLN4 | c.872G>C p.R291P | Missense Mutation (SNP) | VAF 4/40 reads (10%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.845); called by muse, mutect2
- HECW1 | c.673C>A p.P225T | Missense Mutation (SNP) | VAF 18/196 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- HEPH | c.2162A>T p.H721L (on ENST00000343002; = p.H454L on NM_014799.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 35/574 reads (6%) | SIFT tolerated (0.84); PolyPhen benign (0.003); called by muse, mutect2
- ICE1 | c.238C>T p.Q80* | Nonsense Mutation (SNP) | VAF 30/674 reads (4%) | called by muse, mutect2
- IFNA7 | c.32T>A p.V11E | Missense Mutation (SNP) | VAF 9/163 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.065); called by muse, mutect2
- IHH | c.1205A>T p.H402L | Missense Mutation (SNP) | VAF 14/136 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2
- IL10RB | c.397G>T p.A133S | Missense Mutation (SNP) | VAF 52/898 reads (6%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.867); called by muse, mutect2
- IMPG2 | c.3522G>T p.E1174D | Missense Mutation (SNP) | VAF 14/382 reads (4%) | SIFT tolerated (0.25); PolyPhen benign (0.054); called by muse, mutect2
- INSRR | c.3803C>T p.A1268V | Missense Mutation (SNP) | VAF 26/475 reads (5%) | SIFT tolerated (0.27); PolyPhen benign (0.022); called by muse, mutect2
- IRF2BPL | c.643A>T p.S215C | Missense Mutation (SNP) | VAF 15/186 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.935); called by muse, mutect2
- ITGAD | c.1468C>A p.Q490K | Missense Mutation (SNP) | VAF 12/80 reads (15%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.462); called by muse, varscan2
- ITIH6 | c.2828A>T p.Q943L | Missense Mutation (SNP) | VAF 6/44 reads (14%) | SIFT tolerated (0.05); PolyPhen benign (0.01); called by mutect2, varscan2
- KCNC4 | c.1755G>T p.K585N | Missense Mutation (SNP) | VAF 16/256 reads (6%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.261); called by muse, mutect2
- KCNH2 | c.2061C>A p.H687Q | Missense Mutation (SNP) | VAF 16/218 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); called by muse, mutect2
- KCTD8 | c.1043G>T p.S348I | Missense Mutation (SNP) | VAF 9/178 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.919); called by muse, mutect2
- KIAA1210 | c.2741C>A p.P914H | Missense Mutation (SNP) | VAF 27/519 reads (5%) | SIFT tolerated (0.2); PolyPhen benign (0.129); called by muse, mutect2
- KIAA1210 | c.2486A>T p.E829V | Missense Mutation (SNP) | VAF 15/294 reads (5%) | SIFT tolerated (0.05); PolyPhen benign (0.275); called by muse, mutect2
- KIF4B | c.1953G>T p.M651I | Missense Mutation (SNP) | VAF 46/1031 reads (4%) | SIFT tolerated (0.22); PolyPhen benign (0.056); called by muse, mutect2
- LAMA2 | c.5009G>A p.R1670K | Missense Mutation (SNP) | VAF 70/1181 reads (6%) | SIFT tolerated (0.11); PolyPhen benign (0.339); called by muse, mutect2
- LAMC3 | c.3952C>A p.L1318M | Missense Mutation (SNP) | VAF 32/455 reads (7%) | SIFT tolerated (0.22); PolyPhen benign (0.146); called by muse, mutect2
- LCT | c.715G>T p.A239S | Missense Mutation (SNP) | VAF 53/1024 reads (5%) | SIFT tolerated (0.59); PolyPhen benign (0.015); called by muse, mutect2
- MBOAT7 | c.251T>A p.L84Q | Missense Mutation (SNP) | VAF 6/150 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); called by muse, mutect2
- MDGA1 | c.1526G>T p.S509I | Missense Mutation (SNP) | VAF 7/73 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.196); called by muse, mutect2
- MGAM | c.1070A>T p.E357V | Missense Mutation (SNP) | VAF 30/651 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- MKI67 | c.6788G>A p.G2263E | Missense Mutation (SNP) | VAF 57/1065 reads (5%) | SIFT tolerated (0.8); PolyPhen probably damaging (0.961); called by muse, mutect2
- MN1 | c.2052G>T p.M684I | Missense Mutation (SNP) | VAF 5/39 reads (13%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- MORC4 | c.899C>G p.A300G | Missense Mutation (SNP) | VAF 28/744 reads (4%) | SIFT deleterious (0); PolyPhen benign (0.036); called by muse, mutect2
- MSH4 | c.821A>C p.Y274S | Missense Mutation (SNP) | VAF 9/160 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.873); called by muse, mutect2
- MTCP1 | c.254G>T p.W85L | Missense Mutation (SNP) | VAF 29/586 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); called by muse, mutect2
- MTNR1A | c.209C>G p.A70G | Missense Mutation (SNP) | VAF 64/1318 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); called by muse, mutect2
- MTUS2 | c.559G>T p.V187F | Missense Mutation (SNP) | VAF 13/354 reads (4%) | SIFT deleterious (0.04); PolyPhen benign (0.181); called by muse, mutect2
- MUC16 | c.36605-1G>T p.X12202_splice | Splice Site (SNP) | VAF 10/251 reads (4%) | called by muse, mutect2
- MUC16 | c.27235A>G p.I9079V | Missense Mutation (SNP) | VAF 26/394 reads (7%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.031); called by muse, mutect2
- MUC16 | c.9216G>T p.Q3072H | Missense Mutation (SNP) | VAF 30/666 reads (5%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.843); called by muse, mutect2
- MXRA8 | c.7C>A p.L3M | Missense Mutation (SNP) | VAF 13/114 reads (11%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.879); called by muse, mutect2
- MYBPC3 | c.871G>T p.G291W | Missense Mutation (SNP) | VAF 17/573 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- MYO18B | c.6296C>A p.T2099K | Missense Mutation (SNP) | VAF 38/839 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2
- NACA2 | c.540C>A p.D180E | Missense Mutation (SNP) | VAF 130/1262 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.168); called by muse, mutect2, varscan2
- NAIF1 | c.172G>T p.V58L | Missense Mutation (SNP) | VAF 8/132 reads (6%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.448); called by muse, mutect2
- NBAS | c.2415G>T p.L805F | Missense Mutation (SNP) | VAF 39/896 reads (4%) | SIFT tolerated (0.07); PolyPhen benign (0.343); called by muse, mutect2
- NBAS | c.1855G>T p.G619W | Missense Mutation (SNP) | VAF 54/964 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); called by muse, mutect2
- NCF4 | c.146G>T p.G49V | Missense Mutation (SNP) | VAF 86/855 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- NDNF | c.1411G>T p.G471C | Missense Mutation (SNP) | VAF 31/371 reads (8%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.556); called by muse, mutect2
- NDST4 | c.2064G>T p.K688N | Missense Mutation (SNP) | VAF 34/475 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- NDST4 | c.1623G>T p.Q541H | Missense Mutation (SNP) | VAF 21/486 reads (4%) | SIFT tolerated (0.23); PolyPhen benign (0.001); called by muse, mutect2
- NGFR | c.982+2T>A p.X328_splice | Splice Site (SNP) | VAF 8/60 reads (13%) | called by mutect2, varscan2
- NLRP7 | c.172C>A p.L58M | Missense Mutation (SNP) | VAF 71/1313 reads (5%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); called by muse, mutect2
- NOS2 | c.158A>T p.Q53L | Missense Mutation (SNP) | VAF 20/348 reads (6%) | SIFT tolerated (0.65); PolyPhen benign (0); called by muse, mutect2
- NRXN2 | c.3833G>T p.W1278L | Missense Mutation (SNP) | VAF 44/890 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); called by muse, mutect2
- NUDCD1 | c.1570G>T p.A524S | Missense Mutation (SNP) | VAF 16/477 reads (3%) | SIFT tolerated (0.89); PolyPhen benign (0.003); called by muse, mutect2
- OR11H12 | c.31C>A p.L11I | Missense Mutation (SNP) | VAF 34/1068 reads (3%) | SIFT tolerated (0.41); PolyPhen benign (0.005); called by muse, mutect2
- OR2L5 | c.224C>A p.T75K | Missense Mutation (SNP) | VAF 45/886 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.716); called by muse, mutect2
- OR2T27 | c.730C>A p.H244N | Missense Mutation (SNP) | VAF 27/191 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, varscan2
- OR5J2 | c.702A>T p.R234S | Missense Mutation (SNP) | VAF 28/373 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.446); called by muse, mutect2
- OR7A17 | c.587A>T p.D196V | Missense Mutation (SNP) | VAF 29/552 reads (5%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.438); called by muse, mutect2
- OR8K5 | c.819G>T p.M273I | Missense Mutation (SNP) | VAF 17/450 reads (4%) | SIFT tolerated, low confidence (0.34); PolyPhen benign (0.003); called by muse, mutect2
- PABPC5 | c.552A>T p.E184D | Missense Mutation (SNP) | VAF 36/708 reads (5%) | SIFT deleterious (0.01); PolyPhen benign (0.225); called by muse, mutect2
- PABPN1 | c.614G>T p.C205F | Missense Mutation (SNP) | VAF 70/1396 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.472); called by muse, mutect2
- PADI1 | c.1091A>T p.K364I | Missense Mutation (SNP) | VAF 20/236 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- PCDHA10 | c.1109T>A p.L370Q | Missense Mutation (SNP) | VAF 13/353 reads (4%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- PCDHB12 | c.2233C>A p.L745M | Missense Mutation (SNP) | VAF 28/378 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- PCDHB2 | c.70G>T p.G24C | Missense Mutation (SNP) | VAF 20/330 reads (6%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0.046); called by muse, mutect2
- PCDHGA10 | c.463C>A p.R155S | Missense Mutation (SNP) | VAF 50/770 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.746); called by muse, mutect2
- PCDHGA11 | c.449G>T p.G150V | Missense Mutation (SNP) | VAF 23/293 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.852); called by muse, mutect2
- PCSK2 | c.326G>A p.R109Q | Missense Mutation (SNP) | VAF 30/719 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); called by muse, mutect2
- PGM2 | c.1682G>T p.G561V | Missense Mutation (SNP) | VAF 30/526 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- PIK3AP1 | c.1783G>T p.D595Y | Missense Mutation (SNP) | VAF 24/448 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- PLCB1 | c.3061C>A p.Q1021K | Missense Mutation (SNP) | VAF 12/222 reads (5%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.55); called by muse, mutect2
- PLEKHG2 | c.3469G>T p.V1157F | Missense Mutation (SNP) | VAF 21/406 reads (5%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.172); called by muse, mutect2
- PLG | c.85C>T p.Q29* | Nonsense Mutation (SNP) | VAF 35/801 reads (4%) | called by muse, mutect2
- POLD2 | c.67A>T p.T23S | Missense Mutation (SNP) | VAF 19/402 reads (5%) | SIFT tolerated (0.2); PolyPhen benign (0.104); called by muse, mutect2
- PPM1H | c.820G>T p.V274L | Missense Mutation (SNP) | VAF 40/815 reads (5%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.457); called by muse, mutect2
- PPP4R3C | c.616G>T p.E206* | Nonsense Mutation (SNP) | VAF 26/501 reads (5%) | called by muse, mutect2
- PRKDC | c.1366G>T p.V456L | Missense Mutation (SNP) | VAF 33/961 reads (3%) | SIFT tolerated (0.41); PolyPhen benign (0.001); called by muse, mutect2
- PRR23C | c.14C>A p.P5H | Missense Mutation (SNP) | VAF 7/57 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PRSS1 | c.168G>T p.Q56H | Missense Mutation (SNP) | VAF 32/353 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.163); called by muse, mutect2
- PTPRO | c.152G>T p.S51I | Missense Mutation (SNP) | VAF 42/756 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.416); called by muse, mutect2
- RC3H1 | c.1292G>T p.G431V | Missense Mutation (SNP) | VAF 38/610 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- RELL2 | c.874C>A p.H292N | Missense Mutation (SNP) | VAF 12/110 reads (11%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- RNFT2 | c.1057G>T p.G353C | Missense Mutation (SNP) | VAF 24/539 reads (4%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.921); called by muse, mutect2
- RPAP3 | c.605A>T p.K202M | Missense Mutation (SNP) | VAF 27/443 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2
- RPTN | c.2081G>T p.R694M | Missense Mutation (SNP) | VAF 34/488 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.72); called by muse, mutect2
- RTL1 | c.3164C>A p.P1055H | Missense Mutation (SNP) | VAF 6/111 reads (5%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.869); called by muse, mutect2
- SAMD9 | c.263T>A p.M88K | Missense Mutation (SNP) | VAF 36/866 reads (4%) | SIFT tolerated (0.95); PolyPhen benign (0); called by muse, mutect2
- SCARF2 | c.1424+1G>T p.X475_splice | Splice Site (SNP) | VAF 5/98 reads (5%) | called by muse, mutect2
- SDK2 | c.5339G>T p.G1780V | Missense Mutation (SNP) | VAF 18/159 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); called by muse, varscan2
- SHROOM4 | c.82G>T p.G28C | Missense Mutation (SNP) | VAF 14/254 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- SHTN1 | c.399G>T p.E133D | Missense Mutation (SNP) | VAF 30/352 reads (9%) | SIFT tolerated (0.6); PolyPhen benign (0.003); called by muse, mutect2
- SLC12A3 | c.1613G>T p.C538F | Missense Mutation (SNP) | VAF 59/974 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- SLC22A16 | c.158G>T p.R53M | Missense Mutation (SNP) | VAF 7/147 reads (5%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.592); called by muse, mutect2
- SLC34A1 | c.443C>A p.A148D | Missense Mutation (SNP) | VAF 32/543 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2
- SLC36A3 | c.1206C>A p.S402R | Missense Mutation (SNP) | VAF 18/441 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- SLITRK1 | c.1281G>T p.W427C | Missense Mutation (SNP) | VAF 45/945 reads (5%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.827); called by muse, mutect2
- SLITRK5 | c.1226A>T p.Y409F | Missense Mutation (SNP) | VAF 16/207 reads (8%) | SIFT tolerated (0.13); PolyPhen benign (0.031); called by muse, mutect2
- SPTA1 | c.6530+7T>C | Splice Region (SNP) | VAF 51/1023 reads (5%) | called by muse, mutect2
- SPTAN1 | c.447G>T p.Q149H | Missense Mutation (SNP) | VAF 54/1474 reads (4%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.99); called by muse, mutect2
- SRPX2 | c.709C>A p.H237N | Missense Mutation (SNP) | VAF 47/838 reads (6%) | SIFT tolerated (0.08); PolyPhen benign (0.039); called by muse, mutect2
- ST6GAL2 | c.1094T>A p.V365D | Missense Mutation (SNP) | VAF 44/477 reads (9%) | PolyPhen probably damaging (0.979); called by muse, mutect2
- STON2 | c.1888G>T p.V630L (on ENST00000649389 / NM_001366849.2; = p.V573L on NM_001256430.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 39/715 reads (5%) | SIFT tolerated (0.36); PolyPhen benign (0.327); called by muse, mutect2
- SYN1 | c.1079G>C p.C360S | Missense Mutation (SNP) | VAF 40/838 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- SYNGR1 | c.187C>A p.R63S | Missense Mutation (SNP) | VAF 42/311 reads (14%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.473); called by muse, mutect2, varscan2
- TAB3 | c.550T>C p.Y184H | Missense Mutation (SNP) | VAF 32/548 reads (6%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.999); called by muse, mutect2
- TANC1 | c.2144A>T p.Q715L | Missense Mutation (SNP) | VAF 12/222 reads (5%) | SIFT deleterious (0); PolyPhen benign (0.039); called by muse, mutect2
- TENT5C | c.331G>A p.V111M | Missense Mutation (SNP) | VAF 81/1322 reads (6%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.855); called by muse, mutect2
- THSD7B | c.1869T>A p.D623E | Missense Mutation (SNP) | VAF 32/424 reads (8%) | SIFT tolerated (1); PolyPhen benign (0.041); called by muse, mutect2
- TIAM1 | c.4221C>A p.S1407R | Missense Mutation (SNP) | VAF 14/177 reads (8%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.941); called by muse, mutect2
- TM7SF2 | c.1031G>T p.G344V | Missense Mutation (SNP) | VAF 26/406 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- TNP1 | c.133G>T p.D45Y | Missense Mutation (SNP) | VAF 64/1214 reads (5%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.957); called by muse, mutect2
- TRBV27 | c.49G>T p.G17C | Missense Mutation (SNP) | VAF 34/443 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2
- TTC12 | c.996G>T p.Q332H | Missense Mutation (SNP) | VAF 7/94 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.809); called by muse, mutect2
- TYRO3 | c.206T>A p.M69K | Missense Mutation (SNP) | VAF 24/706 reads (3%) | SIFT tolerated (0.51); PolyPhen benign (0.183); called by muse, mutect2
- UGT1A10 | c.615G>T p.E205D | Missense Mutation (SNP) | VAF 44/885 reads (5%) | SIFT deleterious (0.02); PolyPhen benign (0.393); called by muse, mutect2
- USP48 | c.2473G>T p.G825* | Nonsense Mutation (SNP) | VAF 36/716 reads (5%) | called by muse, mutect2
- UVSSA | c.521G>T p.R174I | Missense Mutation (SNP) | VAF 22/406 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.732); called by muse, mutect2
- WAS | c.647C>A p.P216Q | Missense Mutation (SNP) | VAF 22/464 reads (5%) | SIFT tolerated (0.25); PolyPhen benign (0.119); called by muse, mutect2
- WASHC5 | c.1704G>T p.M568I | Missense Mutation (SNP) | VAF 62/1188 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.785); called by muse, mutect2
- ZADH2 | c.748G>C p.G250R | Missense Mutation (SNP) | VAF 14/208 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- ZAN | c.1301C>G p.S434* | Nonsense Mutation (SNP) | VAF 60/604 reads (10%) | called by muse, mutect2
- ZAN | c.3584G>A p.R1195K | Missense Mutation (SNP) | VAF 17/220 reads (8%) | SIFT tolerated (0.18); PolyPhen benign (0.163); called by muse, mutect2
- ZBTB47 | c.1328G>T p.R443L | Missense Mutation (SNP) | VAF 18/230 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.02); called by muse, mutect2
- ZCCHC18 | c.916C>A p.Q306K | Missense Mutation (SNP) | VAF 28/298 reads (9%) | SIFT tolerated (0.17); PolyPhen benign (0.059); called by muse, mutect2
- ZNF135 | c.396C>A p.H132Q (on ENST00000313434 / NM_001289401.2; = p.H144Q on NM_003436.4) | Missense Mutation (SNP) | VAF 24/404 reads (6%) | SIFT tolerated (0.78); PolyPhen benign (0); called by muse, mutect2
- ZNF8 | c.445G>T p.A149S | Missense Mutation (SNP) | VAF 14/414 reads (3%) | SIFT tolerated (0.74); PolyPhen benign (0.001); called by muse, mutect2
- ZNF804A | c.2315G>T p.R772L | Missense Mutation (SNP) | VAF 18/412 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); called by muse, mutect2
- ZNF835 | c.67C>A p.Q23K | Missense Mutation (SNP) | VAF 30/474 reads (6%) | SIFT tolerated (0.86); PolyPhen benign (0); called by muse, mutect2
- ZNF90 | c.1364G>T p.C455F | Missense Mutation (SNP) | VAF 33/796 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2
- ZSWIM6 | c.1060A>T p.S354C | Missense Mutation (SNP) | VAF 39/592 reads (7%) | SIFT tolerated (0.05); PolyPhen probably damaging (1); called by muse, mutect2
- ACRBP | c.1506G>T p.R502= | Silent (SNP) | VAF 18/345 reads (5%) | called by muse, mutect2
- ADAM19 | c.762G>A p.R254= | Silent (SNP) | VAF 16/219 reads (7%) | called by muse, mutect2
- ADAM33 | c.117A>G p.P39= | Silent (SNP) | VAF 12/248 reads (5%) | called by muse, mutect2
- ADAMTS16 | c.2553T>A p.V851= | Silent (SNP) | VAF 27/372 reads (7%) | called by muse, mutect2
- ADCYAP1R1 | c.813C>A p.I271= | Silent (SNP) | VAF 35/339 reads (10%) | called by muse, mutect2, varscan2
- AFF2 | c.2667C>A p.P889= | Silent (SNP) | VAF 22/356 reads (6%) | called by muse, mutect2
- AKR7L | c.609G>C p.L203= | Silent (SNP) | VAF 20/340 reads (6%) | catalogued as COSV101334209; called by muse, mutect2
- AP002512.3 | c.594G>T p.V198= | Silent (SNP) | VAF 20/426 reads (5%) | called by muse, mutect2
- AXL | c.1725G>C p.T575= (on ENST00000301178 / NM_021913.5; = p.T566= on NM_001699.6) | Silent (SNP) | VAF 29/398 reads (7%) | catalogued as rs1338596207; called by muse, mutect2
- BCAS3 | c.1098A>T p.L366= | Silent (SNP) | VAF 24/395 reads (6%) | called by muse, mutect2
- BCORL1 | c.2976C>A p.S992= | Silent (SNP) | VAF 19/480 reads (4%) | catalogued as COSV54407300; called by muse, mutect2
- BHMT | c.1023C>A p.P341= | Silent (SNP) | VAF 27/329 reads (8%) | called by muse, mutect2
- C22orf42 | c.706C>A p.R236= | Silent (SNP) | VAF 42/537 reads (8%) | catalogued as COSV101173346; called by muse, mutect2
- CD109 | c.1914C>A p.L638= | Silent (SNP) | VAF 22/554 reads (4%) | called by muse, mutect2
- CENPH | c.585A>C p.I195= | Silent (SNP) | VAF 20/345 reads (6%) | called by muse, mutect2
- COG8 | c.12G>C p.A4= | Silent (SNP) | VAF 32/454 reads (7%) | called by muse, mutect2
- CPEB1 | c.1852C>A p.R618= (on ENST00000617958; = p.R553= on NM_030594.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 7/160 reads (4%) | called by muse, mutect2
- D2HGDH | c.480C>T p.H160= | Silent (SNP) | VAF 12/255 reads (5%) | called by muse, mutect2
- DCHS2 | c.1821C>A p.A607= | Silent (SNP) | VAF 8/164 reads (5%) | called by muse, mutect2
- DLAT | c.321C>T p.T107= | Silent (SNP) | VAF 108/1844 reads (6%) | called by muse, mutect2
- DNER | c.1893C>A p.L631= | Silent (SNP) | VAF 33/381 reads (9%) | called by muse, mutect2
- EFNB2 | c.21C>T p.S7= | Silent (SNP) | VAF 21/319 reads (7%) | called by muse, mutect2
- EPHA10 | c.2535G>T p.R845= | Silent (SNP) | VAF 30/612 reads (5%) | called by muse, mutect2
- FAT4 | c.1545C>T p.V515= | Silent (SNP) | VAF 40/650 reads (6%) | called by muse, mutect2
- FGB | c.1011C>A p.P337= | Silent (SNP) | VAF 21/278 reads (8%) | catalogued as COSV57418095; called by muse, mutect2
- GCN1 | c.4260G>T p.A1420= | Silent (SNP) | VAF 10/246 reads (4%) | catalogued as COSV100325952; called by muse, mutect2
- GIMAP6 | c.459G>T p.G153= | Silent (SNP) | VAF 36/440 reads (8%) | called by muse, mutect2
- GPR158 | c.1962T>A p.T654= | Silent (SNP) | VAF 24/458 reads (5%) | catalogued as COSV66264528; called by muse, mutect2
- IGSF9B | c.27A>T p.I9= | Silent (SNP) | VAF 26/415 reads (6%) | called by muse, mutect2
- IL7R | c.744G>A p.L248= | Silent (SNP) | VAF 72/1366 reads (5%) | catalogued as COSV57411421; called by muse, mutect2
- INSRR | c.3801G>T p.G1267= | Silent (SNP) | VAF 26/476 reads (5%) | catalogued as rs1367571667; called by muse, mutect2
- ITGB5 | c.306A>G p.A102= | Silent (SNP) | VAF 19/386 reads (5%) | called by muse, mutect2
- ITGB8 | c.1788A>T p.S596= | Silent (SNP) | VAF 102/968 reads (11%) | called by muse, mutect2, varscan2
- KCNF1 | c.924G>C p.S308= | Silent (SNP) | VAF 6/69 reads (9%) | catalogued as COSV54464984; called by muse, mutect2
- KCNH4 | c.1179G>T p.P393= | Silent (SNP) | VAF 18/170 reads (11%) | called by muse, mutect2, varscan2
- KIAA1671 | c.597G>T p.L199= | Silent (SNP) | VAF 8/198 reads (4%) | called by muse, mutect2
- L1TD1 | c.1671T>C p.S557= | Silent (SNP) | VAF 44/894 reads (5%) | catalogued as rs770543773; called by muse, mutect2
- LCLAT1 | c.1053G>A p.L351= | Silent (SNP) | VAF 38/600 reads (6%) | catalogued as rs371735450; called by muse, mutect2
- LRFN1 | c.213G>T p.R71= | Silent (SNP) | VAF 3/29 reads (10%) | catalogued as rs1419773822; called by muse, mutect2
- LRRC66 | c.2268T>C p.N756= | Silent (SNP) | VAF 18/354 reads (5%) | called by muse, mutect2
- MAD1L1 | c.898C>T p.L300= | Silent (SNP) | VAF 30/299 reads (10%) | called by muse, mutect2, varscan2
- MARK1 | c.1530C>A p.T510= | Silent (SNP) | VAF 32/506 reads (6%) | called by muse, mutect2
- MORC4 | c.900C>A p.A300= | Silent (SNP) | VAF 26/738 reads (4%) | called by muse, mutect2
- MTMR4 | c.2850G>T p.G950= | Silent (SNP) | VAF 33/258 reads (13%) | called by muse, mutect2, varscan2
- MUC16 | c.18825A>G p.S6275= | Silent (SNP) | VAF 20/383 reads (5%) | catalogued as COSV67481001; called by muse, mutect2
- MUC16 | c.9753C>A p.A3251= | Silent (SNP) | VAF 40/494 reads (8%) | catalogued as COSV67480164; called by muse, mutect2
- MUC17 | c.11319C>G p.T3773= | Silent (SNP) | VAF 29/247 reads (12%) | called by muse, mutect2, varscan2
- MYBPC3 | c.393C>A p.A131= | Silent (SNP) | VAF 7/155 reads (5%) | catalogued as rs1180272933; called by muse, mutect2
- NFIL3 | c.798A>T p.R266= | Silent (SNP) | VAF 17/415 reads (4%) | called by muse, mutect2
- NKX1-2 | c.108C>T p.L36= | Silent (SNP) | VAF 11/238 reads (5%) | catalogued as rs1279194989; called by muse, mutect2
- OPN1LW | c.312C>A p.V104= | Silent (SNP) | VAF 16/352 reads (5%) | called by muse, mutect2
- OR1M1 | c.192C>T p.A64= | Silent (SNP) | VAF 12/199 reads (6%) | called by muse, mutect2
- PAXIP1 | c.2067G>C p.P689= | Silent (SNP) | VAF 54/802 reads (7%) | catalogued as COSV101249420, COSV68186789; called by muse, mutect2
- PCDH19 | c.3411C>A p.S1137= (on ENST00000373034 / NM_001184880.2; = p.S1089= on NM_020766.3) | Silent (SNP) | VAF 27/664 reads (4%) | catalogued as COSV55272741; called by muse, mutect2
- PCDH9 | c.2358C>T p.D786= | Silent (SNP) | VAF 30/474 reads (6%) | called by muse, mutect2
- PEG3 | c.4584C>A p.A1528= | Silent (SNP) | VAF 23/377 reads (6%) | called by muse, mutect2
- PLEC | c.2457G>T p.L819= (on ENST00000322810 / NM_201380.4; = p.L709= on NM_000445.5) | Silent (SNP) | VAF 14/276 reads (5%) | catalogued as rs1554716461; called by muse, mutect2
- PRRC2A | c.5964G>A p.L1988= | Silent (SNP) | VAF 14/258 reads (5%) | called by muse, mutect2
- RALYL | c.612C>A p.T204= | Silent (SNP) | VAF 26/494 reads (5%) | called by muse, mutect2
- RASGRF1 | c.711C>T p.S237= | Silent (SNP) | VAF 20/410 reads (5%) | called by muse, mutect2
- RBM15B | c.447G>C p.A149= | Silent (SNP) | VAF 16/300 reads (5%) | catalogued as COSV60371977; called by muse, mutect2
- RGPD4 | c.4767C>A p.A1589= | Silent (SNP) | VAF 110/2017 reads (5%) | called by muse, mutect2
- RYR1 | c.3903C>T p.R1301= | Silent (SNP) | VAF 9/163 reads (6%) | catalogued as rs1414294757; called by muse, mutect2
- RYR2 | c.5241C>A p.G1747= | Silent (SNP) | VAF 18/214 reads (8%) | called by muse, mutect2
- SAA2-SAA4 | c.459C>A p.L153= | Silent (SNP) | VAF 27/314 reads (9%) | called by muse, mutect2
- SCCPDH | c.333A>G p.K111= | Silent (SNP) | VAF 36/740 reads (5%) | called by muse, mutect2
- SDK1 | c.3492G>T p.R1164= | Silent (SNP) | VAF 24/193 reads (12%) | called by muse, mutect2, varscan2
- SEC23B | c.618G>T p.L206= | Silent (SNP) | VAF 54/1136 reads (5%) | catalogued as rs184842146; called by muse, mutect2
- SEMA4B | c.1396C>T p.L466= | Silent (SNP) | VAF 5/77 reads (6%) | catalogued as rs1327999081; called by muse, mutect2
- SHROOM4 | c.81G>T p.G27= | Silent (SNP) | VAF 14/252 reads (6%) | called by muse, mutect2
- SKOR1 | c.66C>A p.S22= | Silent (SNP) | VAF 28/722 reads (4%) | called by muse, mutect2
- SLC34A1 | c.444C>A p.A148= | Silent (SNP) | VAF 32/546 reads (6%) | called by muse, mutect2
- SMCO1 | c.111T>C p.D37= | Silent (SNP) | VAF 32/598 reads (5%) | catalogued as rs1279602281; called by muse, mutect2
- SYTL4 | c.1791G>A p.L597= | Silent (SNP) | VAF 32/690 reads (5%) | called by muse, mutect2
- TBX4 | c.1413T>C p.F471= | Silent (SNP) | VAF 3/26 reads (12%) | catalogued as COSV99540257; called by muse, mutect2
- TESC | c.255C>T p.F85= | Silent (SNP) | VAF 26/472 reads (6%) | catalogued as rs570252037, COSV58813465; called by muse, mutect2
- TMC2 | c.2658C>A p.A886= | Silent (SNP) | VAF 13/356 reads (4%) | called by muse, mutect2
- TRPV5 | c.2064G>T p.L688= | Silent (SNP) | VAF 76/934 reads (8%) | called by muse, mutect2
- USP34 | c.8634C>T p.I2878= | Silent (SNP) | VAF 47/698 reads (7%) | catalogued as COSV68404326; called by muse, mutect2
- VIRMA | c.3342A>T p.I1114= | Silent (SNP) | VAF 40/769 reads (5%) | called by muse, mutect2
- YWHAG | c.159G>T p.V53= | Silent (SNP) | VAF 32/494 reads (6%) | called by muse, mutect2
- ZBTB39 | c.1308G>T p.L436= | Silent (SNP) | VAF 13/192 reads (7%) | catalogued as COSV100268307; called by muse, mutect2
- ZFHX2 | c.3528C>T p.T1176= | Silent (SNP) | VAF 9/143 reads (6%) | catalogued as rs1010902104; called by muse, mutect2
- ZIC4 | c.861G>T p.V287= | Silent (SNP) | VAF 11/206 reads (5%) | called by muse, mutect2
- ZNF726 | c.9G>T p.L3= | Silent (SNP) | VAF 48/1088 reads (4%) | called by muse, mutect2
- ABCC2 | c.-7A>T | 5'UTR (SNP) | VAF 54/1244 reads (4%) | called by muse, mutect2
- ABCC8 | c.2041-26T>C | Intron (SNP) | VAF 24/526 reads (5%) | called by muse, mutect2
- ADH5P5 | chr5:23977810 C>A | 5'Flank (SNP) | VAF 22/282 reads (8%) | called by muse, mutect2
- AL133467.5 | n.110G>T | RNA (SNP) | VAF 31/662 reads (5%) | called by muse, mutect2
- AL355390.1 | n.485C>A | RNA (SNP) | VAF 26/587 reads (4%) | called by muse, mutect2
- AL450442.1 | n.696G>T | RNA (SNP) | VAF 38/765 reads (5%) | called by muse, mutect2
- AP004607.5 | n.191G>T | RNA (SNP) | VAF 20/438 reads (5%) | called by muse, mutect2
- C19orf12 | chr19:29702195 G>A | 3'Flank (SNP) | VAF 10/189 reads (5%) | called by muse, mutect2
- C2orf72 | c.*26G>T | 3'UTR (SNP) | VAF 34/414 reads (8%) | called by muse, mutect2
- CABIN1 | c.-25G>T | 5'UTR (SNP) | VAF 52/1014 reads (5%) | catalogued as COSV54085131; called by muse, mutect2
- CD1C | c.*46C>A | 3'UTR (SNP) | VAF 38/730 reads (5%) | called by muse, mutect2
- DNMT1 | c.445+154G>A | Intron (SNP) | VAF 5/83 reads (6%) | catalogued as rs1162240275; called by muse, mutect2
- ESRRB | c.1501-9C>A | Intron (SNP) | VAF 15/429 reads (3%) | called by muse, mutect2
- F2RL2 | c.-4C>A | 5'UTR (SNP) | VAF 46/674 reads (7%) | called by muse, mutect2
- FOLH1B | n.1222T>C | RNA (SNP) | VAF 34/650 reads (5%) | called by muse, mutect2
- FSHR | c.-7C>A | 5'UTR (SNP) | VAF 39/749 reads (5%) | called by muse, mutect2
- GABRA6 | c.39-38G>A | Intron (SNP) | VAF 32/622 reads (5%) | called by muse, mutect2
- GLB1L2 | c.559-286G>C | Intron (SNP) | VAF 24/520 reads (5%) | called by muse, mutect2
- GNG5P2 | n.14C>A | RNA (SNP) | VAF 11/174 reads (6%) | called by muse, mutect2
- GRN | c.264+33A>G | Intron (SNP) | VAF 28/586 reads (5%) | called by muse, mutect2
- INO80C | c.157-6881G>A | Intron (SNP) | VAF 14/191 reads (7%) | catalogued as rs1043972603; called by muse, mutect2
- LIPH | c.-49G>C | 5'UTR (SNP) | VAF 19/291 reads (7%) | called by muse, mutect2
- MIR509-1 | n.7G>T | RNA (SNP) | VAF 17/317 reads (5%) | called by muse, mutect2
- MLIP | c.613-11475G>T | Intron (SNP) | VAF 26/370 reads (7%) | called by muse, mutect2
- MRPL28 | c.*260G>T | 3'UTR (SNP) | VAF 11/60 reads (18%) | called by muse, mutect2, varscan2
- MT1H | c.94+124C>G | Intron (SNP) | VAF 18/268 reads (7%) | called by muse, mutect2
- MTTP | chr4:99570752 A>C | 5'Flank (SNP) | VAF 28/648 reads (4%) | called by muse, mutect2
- NAMPTP1 | n.1224G>T | RNA (SNP) | VAF 48/1005 reads (5%) | called by muse, mutect2
- NKD2 | c.788-273G>T | Intron (SNP) | VAF 10/87 reads (11%) | called by muse, mutect2, varscan2
- OLFM1 | chr9:135087432 G>T | 5'Flank (SNP) | VAF 3/47 reads (6%) | called by muse, mutect2
- PRB1 | c.101-533T>A | Intron (SNP) | VAF 68/1231 reads (6%) | called by muse, mutect2
- PSG6 | chr19:42902399 A>G | 3'Flank (SNP) | VAF 17/416 reads (4%) | called by muse, mutect2
- PSG9 | c.1243+206T>A | Intron (SNP) | VAF 3/29 reads (10%) | called by muse, mutect2
- SCUBE1 | c.844+20T>A | Intron (SNP) | VAF 27/303 reads (9%) | called by muse, mutect2
- SLC6A8 | c.778-68G>T | Intron (SNP) | VAF 14/136 reads (10%) | called by muse, mutect2, varscan2
- SPANXN4 | c.-7C>A | 5'UTR (SNP) | VAF 22/290 reads (8%) | called by muse, mutect2
- SSPOP | n.12613G>T | RNA (SNP) | VAF 20/151 reads (13%) | called by muse, mutect2, varscan2
- SYP | c.227+14C>A | Intron (SNP) | VAF 11/118 reads (9%) | called by muse, mutect2
- TARS3 | c.2260+931G>T | Intron (SNP) | VAF 27/804 reads (3%) | called by muse, mutect2
- TCEAL4 | c.-22-415C>A | Intron (SNP) | VAF 10/304 reads (3%) | called by muse, mutect2
- THOC2 | c.3503+77G>A | Intron (SNP) | VAF 27/401 reads (7%) | called by muse, mutect2
- TRDN | c.1369+23G>T | Intron (SNP) | VAF 32/340 reads (9%) | called by muse, mutect2
- TREM1 | c.-19G>A | 5'UTR (SNP) | VAF 12/262 reads (5%) | called by muse, mutect2
- TRIM67 | c.1045-12212C>A | Intron (SNP) | VAF 30/554 reads (5%) | called by muse, mutect2
- WT1 | chr11:32438724 G>T | 5'Flank (SNP) | VAF 109/1894 reads (6%) | called by muse, mutect2
- ZNF783 | c.*21G>T | 3'UTR (SNP) | VAF 46/700 reads (7%) | catalogued as rs756663324; called by muse, mutect2
- ZNF99 | c.*3371G>A | 3'UTR (SNP) | VAF 6/81 reads (7%) | called by muse, mutect2
